Somatic mutation profile of tumor specimen TCGA-2G-AAF4-01A (aliquot TCGA-2G-AAF4-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAF4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.1 years (10,983 days).
Specimen TCGA-2G-AAF4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0870242-c462-48dd-b149-d1ccd5ba3ba0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAF4-10A (Blood Derived Normal), aliquot TCGA-2G-AAF4-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ddc0b0b-579b-40c3-957f-7176be0ac010

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 18/126 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATIC | c.1295_1296del p.S432Cfs*29 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | catalogued as rs750764514; called by pindel, varscan2
- SRCAP | c.8371C>A p.P2791T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV52680538; called by muse, mutect2, varscan2
- CTNND1 | c.2424C>G p.I808M (on ENST00000399050 / NM_001085458.2; = p.I802M on NM_001331.3) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SZT2 | c.115del p.L39Cfs*91 | Frame Shift Del (DEL) | VAF 16/107 reads (15%) | called by mutect2, pindel, varscan2
- UMPS | c.425A>C p.E142A | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.02); called by muse, mutect2
- ITGA6 | c.1716A>G p.L572= (on ENST00000442250; = p.L533= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs1354829121; called by muse, mutect2, varscan2
- PIEZO1 | c.5934C>T p.G1978= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs760875854; called by muse, mutect2, varscan2
- SEC16A | c.4152T>C p.N1384= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
